Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PM, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PM-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

IGD-0.3
Adenocarcinoma, signet ring
cell 849013

Site: Gastric Cardia C16.0
JW 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

I) Product of esophagogastrectomy.

- Poorly differentiated adenocarcinoma with signet ring cells (diffuse type of Lauren) measuring 15.0 x 10.0 x 1.0 cm on the greatest axes, involving the fundus, body and cardia, extending to the esophagus.
- The tumor infiltrates the peritoneum, the perigastric fat and the esophageal adventitia.
- Presence of lymphatic and perineural foci of tumoral infiltration.
- Moderate stromal desmoplasia.
- Circumferential esophageal margin involved by neoplasia.
- Proximal and distal margins uninvolved by neoplasia.

II) Standardized lymphadenectomy.

- * Right paracardic lymph nodes
- Metastatic adenocarcinoma in 4 of the 10 lymph nodes dissected (4/10).
- * Left paracardic lymph nodes
- Metastatic adenocarcinoma in 2 of the 5 lymph nodes dissected (2/5).
- * Lesser curvature
- Metastatic adenocarcinoma in 17 of the 22 lymph nodes dissected (17/22).
- * Short gastric
- Fragment of epiploon with no particularities.
- * Right gastroepiploic
- Metastatic adenocarcinoma (1/2).
- * Suprapyloric
- Fragment of omentum uninvolved by neoplasia.
- * Infrapyloric
- Lymph node uninvolved by neoplasia (0/1).
- * Left gastric artery.
- Metastatic adenocarcinoma in 16 of 20 lymph nodes (16/20).

[page 2 of 2]
- * Common hepatic artery.
- Absence of neoplasia (0/5).

- * Celiac trunk.
- Metastatic adenocarcinoma in 10 of 11 lymph nodes (10/11).

- * Splenic hilum.
- Metastatic adenocarcinoma (5/5).

- * Superior mesenteric vein.
- Absence of neoplasia (0/2).

- * Inferior esophagus.
- Absence of neoplasia (0/5).

- III) Hepatogastric ligament.
- Small lymph node uninvolved by neoplasia amid the adipose tissue.

- IV) Spleen.
- Absence of histological abnormalities worthy of note.

- V) Omentum.
- Uninvolved by neoplasia.

Source: NCI Genomic Data Commons file 702d292e-811d-4b9c-b649-4e9f80b1f741 (TCGA-VQ-A8PM.C55568F6-1060-44CB-B105-00C136A56D79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).